Somatic mutation profile of tumor specimen MP2PRT-PAUMMI-TMP1-A (aliquot MP2PRT-PAUMMI-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAUMMI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (2,016 days).
Specimen MP2PRT-PAUMMI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da6dbbcc-200a-4d92-bd75-9f055c00fdb9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUMMI-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUMMI-NB1-B-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98132cc0-4bc2-46d3-abd0-a0fc561f894a

The open-access MAF lists 65 somatic variants for this specimen: 49 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 14, Nonsense Mutation 4, In Frame Del 1, Intron 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>C p.D835H | Missense Mutation (SNP) | VAF 48/242 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABR | c.1440C>G p.F480L (on ENST00000302538 / NM_021962.5; = p.F443L on NM_001092.5) | Missense Mutation (SNP) | VAF 41/210 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV99348690; called by muse, mutect2, varscan2
- ACSM5 | c.1588G>C p.E530Q | Missense Mutation (SNP) | VAF 66/348 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.208); catalogued as COSV100088497; called by muse, mutect2, varscan2
- ADRA2B | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 94/561 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs371934652; called by muse, mutect2, varscan2
- ASTL | c.992G>T p.G331V | Missense Mutation (SNP) | VAF 96/539 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); catalogued as COSV60905449; called by muse, mutect2, varscan2
- ASTL | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 43/300 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs1433190732, COSV60903516; called by muse, mutect2, varscan2
- ATG2A | c.3601G>A p.E1201K | Missense Mutation (SNP) | VAF 60/342 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as rs759628876, COSV65965823; called by muse, mutect2, varscan2
- C15orf39 | c.1456C>G p.L486V | Missense Mutation (SNP) | VAF 107/578 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1478026112; called by muse, mutect2, varscan2
- CDHR1 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 33/513 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs45567134; ClinVar: uncertain significance; called by muse, mutect2
- CHRM1 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 183/504 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs749521197, COSV61006574; called by muse, mutect2, varscan2
- DCAF8L2 | c.780G>C p.Q260H | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as COSV70550551; called by muse, mutect2
- GABRA2 | c.280C>T p.R94* | Nonsense Mutation (SNP) | VAF 46/145 reads (32%) | catalogued as rs1428045491, COSV100734734, COSV62915909; called by muse, mutect2, varscan2
- GLUD2 | c.1140C>G p.I380M | Missense Mutation (SNP) | VAF 93/291 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.592); catalogued as COSV100047161; called by muse, mutect2, varscan2
- GPC1 | c.1311C>G p.I437M | Missense Mutation (SNP) | VAF 63/417 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as rs1372773870, COSV50866468; called by muse, mutect2, varscan2
- H2BC21 | c.222C>G p.I74M | Missense Mutation (SNP) | VAF 86/471 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.943); catalogued as COSV58611965; called by muse, mutect2, varscan2
- MAMLD1 | c.1748C>T p.S583L | Missense Mutation (SNP) | VAF 57/371 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.356); catalogued as rs1050987096; called by muse, mutect2, varscan2
- NPLOC4 | c.397G>A p.G133S | Missense Mutation (SNP) | VAF 125/306 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as rs1166381765, COSV104402223; called by muse, mutect2, varscan2
- PCDHA6 | c.1512G>T p.L504F | Missense Mutation (SNP) | VAF 38/920 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs1554132112; called by muse, mutect2
- RNF213 | c.800C>T p.S267L | Missense Mutation (SNP) | VAF 51/280 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs1472615318, COSV60627034; called by muse, mutect2, varscan2
- SARM1 | c.1291G>C p.E431Q | Missense Mutation (SNP) | VAF 79/410 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs137938585, COSV99076810; called by muse, mutect2, varscan2
- SLC12A4 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 34/542 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770620661, COSV100312333; called by muse, mutect2
- SPAG16 | c.1144C>G p.P382A | Missense Mutation (SNP) | VAF 82/402 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV100535226; called by muse, mutect2, varscan2
- TTN | c.100408G>T p.E33470* (on ENST00000591111; = p.E26046* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 68/407 reads (17%) | catalogued as COSV100627135; called by muse, mutect2, varscan2
- ZNF10 | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 52/351 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs752454781; called by muse, mutect2, varscan2
- ZNHIT6 | c.74G>T p.S25I | Missense Mutation (SNP) | VAF 88/540 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.051); catalogued as COSV65326878; called by muse, mutect2, varscan2
- C2orf16 | c.340C>A p.Q114K | Missense Mutation (SNP) | VAF 73/422 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- CAPS | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 57/370 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- CEP250 | c.2417-1G>C p.X806_splice | Splice Site (SNP) | VAF 24/284 reads (8%) | called by muse, mutect2
- DNAH10 | c.4825G>C p.E1609Q (on ENST00000409039; = p.E1548Q on NM_207437.3) | Missense Mutation (SNP) | VAF 79/561 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- DNAJC13 | c.4238C>G p.S1413* | Nonsense Mutation (SNP) | VAF 27/393 reads (7%) | called by muse, mutect2
- EDARADD | c.124G>C p.D42H (on ENST00000334232 / NM_145861.4; = p.D32H on NM_080738.4) | Missense Mutation (SNP) | VAF 36/276 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- EFHB | c.612G>C p.E204D | Missense Mutation (SNP) | VAF 24/528 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2
- FAM71D | c.1069G>C p.E357Q | Missense Mutation (SNP) | VAF 19/328 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- FAT3 | c.9999T>G p.D3333E | Missense Mutation (SNP) | VAF 18/478 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.414); called by muse, mutect2
- FILIP1 | c.1801G>C p.D601H | Missense Mutation (SNP) | VAF 54/350 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- FSIP2 | c.7952G>A p.S2651N | Missense Mutation (SNP) | VAF 49/256 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GUF1 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 35/732 reads (5%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.089); called by muse, mutect2
- HGD | c.840G>C p.K280N | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHA2 | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 116/540 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- IRF2BP2 | c.192_198delinsAGAA p.C65_F66delinsE | In Frame Del (DEL) | VAF 160/617 reads (26%) | called by pindel, varscan2*
- LRP1 | c.11048C>G p.S3683* | Nonsense Mutation (SNP) | VAF 12/398 reads (3%) | called by muse, mutect2
- MME | c.1420T>G p.L474V | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MUSK | c.2168A>G p.H723R | Missense Mutation (SNP) | VAF 123/340 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOG | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 119/668 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- NOP56 | c.1551G>C p.L517F | Missense Mutation (SNP) | VAF 65/438 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- RFX2 | c.864G>A p.M288I | Missense Mutation (SNP) | VAF 55/350 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- RNF213 | c.529C>G p.Q177E | Missense Mutation (SNP) | VAF 111/642 reads (17%) | SIFT tolerated (0.82); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 26/448 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2
- ZNF292 | c.7723G>A p.E2575K | Missense Mutation (SNP) | VAF 72/394 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- AKAP10 | c.1572G>A p.L524= | Silent (SNP) | VAF 15/391 reads (4%) | called by muse, mutect2
- C1orf53 | c.171C>G p.P57= | Silent (SNP) | VAF 138/686 reads (20%) | catalogued as COSV100956388; called by muse, varscan2
- CHID1 | c.255C>T p.V85= | Silent (SNP) | VAF 53/307 reads (17%) | called by muse, mutect2, varscan2
- CS | c.439C>T p.L147= | Silent (SNP) | VAF 86/437 reads (20%) | called by muse, mutect2, varscan2
- CTRL | c.585C>T p.I195= | Silent (SNP) | VAF 76/485 reads (16%) | called by muse, mutect2, varscan2
- FRY | c.3828C>T p.I1276= | Silent (SNP) | VAF 115/274 reads (42%) | catalogued as COSV66568750; called by muse, mutect2, varscan2
- GLI2 | c.2412C>T p.R804= (on ENST00000361492 / NM_001374353.1; = p.R821= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 270/807 reads (33%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.1656A>C p.A552= | Silent (SNP) | VAF 230/629 reads (37%) | catalogued as rs868670506; called by muse, mutect2, varscan2
- NLRP2 | c.336G>A p.R112= | Silent (SNP) | VAF 74/400 reads (19%) | called by muse, mutect2, varscan2
- NLRP5 | c.3288G>C p.L1096= | Silent (SNP) | VAF 71/213 reads (33%) | catalogued as rs920311599; called by muse, mutect2, varscan2
- PC | c.783C>T p.Y261= | Silent (SNP) | VAF 135/412 reads (33%) | catalogued as rs144330590; called by muse, mutect2, varscan2
- SLC16A9 | c.1482C>T p.P494= | Silent (SNP) | VAF 59/338 reads (17%) | called by muse, mutect2, varscan2
- TSHR | c.591C>T p.F197= | Silent (SNP) | VAF 22/298 reads (7%) | called by muse, mutect2
- USH2A | c.13054C>T p.L4352= | Silent (SNP) | VAF 158/406 reads (39%) | called by muse, mutect2, varscan2
- FTCDNL1 | c.211+1657C>G | Intron (SNP) | VAF 90/244 reads (37%) | called by muse, mutect2, varscan2
- PRR34 | n.228C>T | RNA (SNP) | VAF 139/752 reads (18%) | called by muse, mutect2, varscan2
